Surgical pathology report (de-identified scan), TCGA case TCGA-IB-AAUO, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Alberta Health Services, specimen TCGA-IB-AAUO-01A (Primary Tumor).

[page 1 of 3]
CONFIDENTIAL

SURGICAL PATHOLOGY REPORT

Time Collected		Time Received	
Time Reported		Time Transmitted	
Order Number		Ordering Provider	
Status	Final	Relevant Information	
		Location	

Report Patient Name:
Demographics (for
verification purposes)

Sex: F

ICD-O-3

SURGICAL PATHOLOGY REPORT

*****Surgical Pathology Report*****

Accession Number
Collected Date/Time
Received Date/Time
Pathologist
Specimen Description
A: Node 8 at
B: Periportal lymph node at
C: Proximal bile duct margin at
D: Whipple's specimen at
Clinical Information
Pancreatic cancer

Adenocarcinoma, duct NOS 8500/3
Site: Pancreas head, C25.0
9/20/14

Diagnosis

- A. Node 8:
- Metastatic adenocarcinoma with focal extracapsular extension.
- B. Periportal Lymph Node:
- Fibroadipose tissue only.
- C. Proximal bile duct margin:
- Inflammatory changes, no neoplasia.
- D. Whipples specimen:
- Poorly differentiated ductal carcinoma invasive into duodenum with perineural, lymphatic and arterial channel invasion, present at the uncinate resection margin
Four peripancreatic lymph nodes with metastatic adenocarcinoma.

Reported by:

Electronically signed by:

Verified:

Synopsis Report

HISTOLOGIC TYPE:

Ductal adenocarcinoma

HISTOLOGIC GRADE:

G3: Poorly differentiated

MICROSCOPIC TUMOR EXTENSION:

Tumor invades duodenal wall

MARGINS:

Margin(s) involved by invasive carcinoma

Uncinate process (retroperitoneal) margin (nonperitonealized surface of the uncinate process)

TREATMENT EFFECT (applicable to carcinomas treated with neoadjuvant therapy):

No prior treatment

LYMPH-VASCULAR INVASION:

Present

PERINEURAL INVASION:

[page 2 of 3]
Present

PRIMARY TUMOR (pT):

pT2: Tumor limited to the pancreas, more than 2 cm in greatest dimension

REGIONAL LYMPH NODES (pN):

pN1: Regional lymph node metastasis

Number examined: 5

Number involved: 5

ADDITIONAL PATHOLOGIC FINDINGS:

Chronic pancreatitis

Gross Description

Received are specimen containers A to D. All requisitions and specimen containers are labelled with the patient's name, The cassettes and identifiers are labelled with the Surgical Number

A: The specimen is received fresh and is subsequently placed into formalin. The container is designated A node 8. The specimen consists of a single possible fragment of lymph node that measures 2.8 x 1.3 x 0.6 cm with attached adipose tissue. The specimen is serially sectioned. The possible lymph node is submitted in A1/2 and the remaining adipose tissue is submitted in A3.

B: Specimen is received fresh. The container is designated B periportal lymph node. The specimen consists of two irregular portions of fibrofatty tissue measuring in aggregate 4 x 2.5 x 0.5 cm. One piece is submitted in toto in B1, other piece is bisected and submitted in toto in B2/3.

C: The specimen consists of a ring-shaped piece of duct which measures 0.2 cm in length and 0.9 cm in diameter. Submitted in toto for quick section in one block.

Specimen is received fresh. The container is designated C proximal bile duct margin.

D: Specimen is received fresh. The container is designated Whipple's. The specimen consists of a segment of duodenum with attached head of pancreas. The bowel measures approximately 25 cm in length with a circumference which ranges from 4 to 6.5 cm. The attached head of pancreas measures 6 x 5 x 2.5 cm. The pancreatic body margin is inked blue, the mesenteric vessel bed margin inked orange, and the uncinate process inked black. Sectioning the pancreas reveals a firm light tan ill defined mass near the uncinate process measuring approximately 2.5 x 2.7 x 1.5 cm. Grossly, the mass comes within 0.1 to 0.2 cm of the black painted uncinate process margin. It is approximately 2.5 cm away from the blue painted pancreatic body margin. Grossly, the mass comes within less than 0.1 cm of the external smooth mesothelial surface of the pancreas. The bile duct is identified and upon opening, contains a stent. The bile duct measures 7 cm in length and has a circumference of 2.5 cm at the proximal resection margin. The circumference as it nears the ampulla is 1.5 cm. The mucosa of the bile duct is tan and is hemorrhagic where the stent is found. The mucosal surface surrounding the ampulla is firm and indurated. Where the mucosa of the ampulla and the duodenum is firm and indurated, also corresponds to the location of the tumor which is found in the pancreas. Found in the adipose adjacent to the pancreas, are four possible lymph nodes ranging in size from 0.7 to 2 cm in greatest dimension. Sections of the specimen as follows:

D1. bile duct margin

D2/3. one section of the mass in the pancreas bisected. These sections also demonstrate the

black painted uncinate process/retroperitoneal margin, as well as the indurated duodenal

mucosa

D4/5. one section of the mass in the pancreas bisected. This section also shows the black

painted uncinate process/retroperitoneal margin, as well as the indurated duodenal

mucosa

D6/7. three sections of bile duct and ampulla

D8/9. shave section of pancreatic body margin bisected

D10. section of grossly unremarkable pancreas with identifiable pancreatic duct.

Also includes

a section of bile duct where the stent was located

D11/12. two further sections of bile duct where the stent was found

D13/14. proximal resection margin of duodenum ? distal portion of stomach bisected

D15. shave section distal margin of duodenum bisected

D16. one possible lymph node bisected

D17. two possible lymph nodes

D18/19. one possible lymph node bisected

Frozen Section Diagnosis

C: Proximal Bile Duct Margin:

- Low grade dysplasia
- Negative for carcinoma

[page 3 of 3]
Reported by:

Accession Number
Encounter Number
Patient Location

hw 1/7/14
BLH 1/25/2013

Source: NCI Genomic Data Commons file ee3a09d0-9ab7-47a5-bd34-3ec842dc4371 (TCGA-IB-AAUO.983120BC-7479-4129-ADBE-D9FAEFC2840E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).